Surgical pathology report (de-identified scan), TCGA case TCGA-HC-7744, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-7744-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

A. Prostate, prostatectomy:

Tumor Characteristics:

1. Histologic type: Adenocarcinoma.
2. Prostate size: 4.5 x 4.0 x 3.7 cm.
3. Tumor quantitation: Extensive, involving almost the entire prostate with neural invasion, seminal vesicle involvement, and involvement of the fatty soft tissue surrounding the prostate.
4. Gleason grade:
- a. Primary pattern: 4/5.
- b. Secondary pattern: 3/5.
- c. Total Gleason score: 7/10.
5. Extraprostatic extension: Yes.
6. Seminal vesicle involvement: Yes.
7. Lymphovascular space invasion: Not diagnostically identified.

Surgical Margin Status:

1. Margins involved: Peripheral margins are focally involved by tumor.

Lymph Node Status:

1. Total number of lymph nodes received: Three lymph nodes identified and negative for tumor involvement.
2. Total number of lymph nodes containing metastatic carcinoma: 0 (0/5).

Other:

1. pTNM stage: pT3b, N0.

B. Biopsy of bladder neck:

Fibrofatty soft tissue negative for malignancy.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: [REDACTED] male with prostate carcinoma

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

A. Prostate seminal vesicle vas deferens and pelvic lymph node left has a clip on it

B. Biopsy of bladder neck

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in two formalin filled containers labeled with the patient's name

A. Container A is additionally labeled 'prostate seminal vesicle vas deferens pelvic lymph nodes' and contains a 44.1 g, 4.5 x 4.0 x 3.7 cm prostate gland received with attached bilateral adnexa having overall dimensions of 4.0 x 2.5 x 1.5 cm. Also received in the same container is a 3.5 cm in length x 0.4 cm in diameter segment of pink-tan cylindrical soft tissue consistent with vas deferens. Two aggregates of yellow-tan fibrofatty soft tissue are also present. The first is 3.0 x 2.5 x 1.0 cm and is designated as left by the presence of a white clip. The second aggregate is 4.5 x 4.0 x 1.5 cm. This aggregate is non-clipped and is designated as right.

The prostatic capsule is pink-tan and shaggy. The specimen is inked as follows: right side - blue and left side - black. The base and apical margins are coned and serially sectioned. The remainder of the specimen is serially sectioned from apex to base to reveal a pink-tan focally cystic cut surface with slight ill-defined yellow-tan discoloration in the right posterior aspect near the base. A discrete mass is not identified. There is diffuse periurethral nodularity with no calculi identified.

On palpation, three ill-defined firm, fatty lymph nodes are identified within the right fibroadipose tissue. They range from 1.0 up to 1.7 cm in greatest dimension.

Within the left fibroadipose tissue are two possible ill-defined lymph nodes 0.6 and 1.0 cm in greatest dimension. Representative sections to include all possible lymph nodes are submitted in cassettes A1 through 20 labeled as follows: 1) right prostate/seminal vesicle junction; 2) left prostate/seminal vesicle junction; 3 and 4) apical margin, perpendicular; 5 and 6) base margin, perpendicular; 7 - 9) right anterior, apex to base; 10 - 12) right posterior, apex to base; 13 - 15) left anterior, apex to base; 16 - 18) left posterior, apex to base; 19) three whole possible lymph nodes, right side; 20) two whole possible lymph nodes, left side. Additionally, a yellow and green cassette are submitted for genomics research, each labeled [REDACTED]

B. Container B is additionally labeled 'biopsy of bladder neck' and contains a 1.0 x 0.6 x 0.4 cm pink-tan, rubbery, irregular soft tissue entirely submitted in cassette B labeled [REDACTED]

Source: NCI Genomic Data Commons file 275a2c30-faed-4632-81ea-4a4edeef07f3 (TCGA-HC-7744.01B8C2AF-BDF8-4627-BF6E-C7A41D929B94.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).